Somatic mutation profile of tumor specimen ALCH-B3ZJ-TTP1-A (aliquot ALCH-B3ZJ-TTP1-A-4-0-D-A799-36) from ALCHEMIST case ALCH-B3ZJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 44.6 years (16,288 days).
Specimen ALCH-B3ZJ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd67814-3987-44d8-bba4-032d1d4520a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZJ-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZJ-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3687ea6-265c-4365-8242-053d3b99a26e

The open-access MAF lists 27 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 78/796 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- USH2A | c.4957C>T p.R1653* | Nonsense Mutation (SNP) | VAF 62/724 reads (9%) | catalogued as rs754768875, CM080609, COSV100239697; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CRYBG2 | c.1018C>T p.L340F | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.659); catalogued as rs551025425; called by muse, mutect2
- DCHS1 | c.7192G>A p.V2398I | Missense Mutation (SNP) | VAF 39/492 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs145939548, COSV55042526; called by muse, mutect2
- DEAF1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as rs1219925185; called by muse, varscan2
- HS6ST2 | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV63710646; called by muse, mutect2
- KIF20B | c.5444G>A p.R1815Q (on ENST00000371728 / NM_001284259.2; = p.R1775Q on NM_016195.4) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53303158, COSV53311184; called by muse, mutect2
- PTGDR | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs780572401; called by muse, mutect2
- TADA1 | c.563C>A p.T188K | Missense Mutation (SNP) | VAF 21/226 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV63310055; called by muse, mutect2
- UCP2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11549044; called by muse, mutect2, varscan2
- UGT2B11 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs1169400462; called by muse, mutect2
- ZNF395 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.036); catalogued as COSV100733875, COSV60428636; called by muse, mutect2, varscan2
- CEP57L1 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 73/561 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCAF15 | c.1664G>C p.C555S | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLRA2 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 74/403 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- LAMC3 | c.2026C>T p.P676S | Missense Mutation (SNP) | VAF 57/555 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.3774A>T p.E1258D | Missense Mutation (SNP) | VAF 62/636 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); called by muse, mutect2
- SETD2 | c.7326_7329del p.T2443Mfs*6 | Frame Shift Del (DEL) | VAF 132/541 reads (24%) | called by mutect2, pindel, varscan2
- ZMYM2 | c.718A>T p.N240Y | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ABCA9 | c.2808G>A p.Q936= | Silent (SNP) | VAF 16/522 reads (3%) | catalogued as COSV60628461; called by muse, mutect2
- DENND2A | c.1671C>T p.I557= | Silent (SNP) | VAF 23/263 reads (9%) | catalogued as rs1310181244, COSV52058150; called by muse, mutect2
- DOCK6 | c.2628G>A p.A876= | Silent (SNP) | VAF 24/220 reads (11%) | catalogued as rs373276793; ClinVar: likely benign; called by muse, mutect2, varscan2
- LHX2 | c.525C>T p.G175= | Silent (SNP) | VAF 9/200 reads (5%) | called by muse, mutect2
- PAX8 | c.465C>T p.P155= | Silent (SNP) | VAF 106/866 reads (12%) | catalogued as rs368339001; called by muse, mutect2, varscan2
- RNF213 | c.1152C>T p.H384= | Silent (SNP) | VAF 99/675 reads (15%) | catalogued as rs147359815; called by muse, mutect2, varscan2
- SNRNP48 | c.396T>C p.C132= | Silent (SNP) | VAF 26/213 reads (12%) | called by muse, mutect2, varscan2
- FAM230J | n.643C>T | RNA (SNP) | VAF 20/408 reads (5%) | catalogued as rs1363665266; called by muse, mutect2
